Somatic mutation profile of tumor specimen TCGA-04-1655-01A (aliquot TCGA-04-1655-01A-01W-0633-09) from TCGA case TCGA-04-1655, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 49.2 years (17,988 days).
Specimen TCGA-04-1655-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d917d5db-5859-4a4e-8597-f07101f5d023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1655-10A (Blood Derived Normal), aliquot TCGA-04-1655-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40d82bec-b01b-4b30-90f9-f18d85dccd5f

The open-access MAF lists 81 somatic variants for this specimen: 59 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 20, Nonsense Mutation 4, 5'Flank 1, Intron 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 87/95 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTR6 | c.1165G>C p.V389L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51840958, COSV51842988; called by muse, mutect2, varscan2
- ANO6 | c.1870G>C p.V624L | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as COSV57666867; called by muse, mutect2, varscan2
- ARAP2 | c.3672A>T p.K1224N | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV58291165; called by muse, mutect2, varscan2
- CACNA1C | c.2796T>A p.I932= | Splice Region (SNP) | VAF 36/466 reads (8%) | catalogued as COSV100213940; called by muse, mutect2
- CACNA1C | c.2797C>A p.L933M | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100213944, COSV100217381; called by muse, mutect2
- CBFA2T2 | c.713C>A p.P238Q | Missense Mutation (SNP) | VAF 18/371 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100656042; called by muse, mutect2
- CCT7 | c.953A>T p.D318V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1391175189, COSV57823457; called by muse, mutect2, varscan2
- CDH10 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs763581492, COSV52589090, COSV52594161; called by muse, mutect2, varscan2
- CHD9 | c.4048A>T p.K1350* | Nonsense Mutation (SNP) | VAF 25/148 reads (17%) | catalogued as COSV54615284; called by muse, mutect2, varscan2
- CLUAP1 | c.389T>G p.L130R | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58894763; called by muse, mutect2, varscan2
- CNTNAP5 | c.3904C>T p.R1302W | Missense Mutation (SNP) | VAF 110/287 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs746429467, COSV70482032, COSV70485093; called by muse, mutect2, varscan2
- CPVL | c.962C>G p.T321R | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as COSV55307453; called by muse, mutect2, varscan2
- DDX54 | c.1589C>A p.S530Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58375688; called by muse, mutect2, varscan2
- DENND4A | c.2492G>C p.R831P | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV101475224, COSV101475495; called by muse, mutect2
- DMXL1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.156); catalogued as COSV100222868; called by muse, mutect2
- DOCK8 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.9); catalogued as rs1318020471, COSV66635586, COSV66636057; called by muse, mutect2, varscan2
- EMCN | c.643A>T p.M215L | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56463329; called by muse, mutect2, varscan2
- EPHB1 | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs56396912; called by muse, mutect2, varscan2
- F5 | c.4637A>G p.Y1546C | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200308026, COSV63127482; called by muse, mutect2, varscan2
- FANCD2 | c.4165C>A p.L1389I | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99810006; called by muse, mutect2
- FAT4 | c.8614C>G p.P2872A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58703955; called by muse, mutect2, varscan2
- GARRE1 | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.297); catalogued as COSV55103132; called by muse, mutect2, varscan2
- HILPDA | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.324); catalogued as COSV99993978; called by muse, mutect2
- HOXD1 | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100514051; called by muse, mutect2
- HTT | c.7286G>A p.G2429D | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs1252276830, COSV100750210; called by muse, mutect2
- IGHG4 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs587754303; called by muse, mutect2
- ITPR1 | c.1826A>T p.H609L (on ENST00000354582; = p.H594L on NM_002222.7) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56999852; called by muse, mutect2, varscan2
- KCNH7 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV100033304, COSV100037182; called by muse, mutect2
- KIAA1109 | c.5449G>C p.E1817Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV52688950, COSV99165462; called by muse, mutect2, varscan2
- KRT78 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV58853278; called by muse, mutect2, varscan2
- KRTAP5-6 | c.373T>G p.C125G | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV66289353; called by muse, mutect2, varscan2
- MEDAG | c.573C>A p.S191R | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as COSV66849983; called by muse, mutect2, varscan2
- MUSK | c.46G>C p.V16L | Missense Mutation (SNP) | VAF 145/463 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs765521756, COSV51894225; called by muse, mutect2, varscan2
- MXD1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV100037379; called by muse, mutect2
- MYH15 | c.5570G>A p.R1857Q | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs576556260, COSV99841823; called by muse, mutect2
- MYH8 | c.1115G>C p.R372P | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67971007; called by muse, mutect2, varscan2
- NT5DC3 | c.1441C>A p.R481S | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101230869; called by muse, mutect2
- OTUD7B | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 55/484 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782785788, COSV64916730, COSV64917276; called by muse, mutect2, varscan2
- PEX2 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 15/323 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100824654; called by muse, mutect2
- PLCH1 | c.2710A>T p.N904Y (on ENST00000340059 / NM_001130960.2; = p.N896Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV58208375; called by muse, mutect2, varscan2
- RNF180 | c.1175G>C p.R392T | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV56964509; called by muse, mutect2, varscan2
- ROBO1 | c.2815C>G p.P939A | Missense Mutation (SNP) | VAF 561/744 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV71397800; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.888); catalogued as rs997214620, COSV58243278; called by muse, mutect2
- RUNX1T1 | c.1597C>T p.R533* (on ENST00000265814 / NM_001198628.1; = p.R506* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/104 reads (19%) | catalogued as COSV56160521, COSV56166871; called by muse, mutect2, varscan2
- RYR2 | c.2134G>C p.E712Q | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV100771858, COSV63699013, COSV63708402; called by muse, mutect2, varscan2
- S100Z | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100460873; called by muse, mutect2
- SCIN | c.1319G>A p.W440* (on ENST00000297029 / NM_001112706.3; = p.W193* on NM_033128.3) | Nonsense Mutation (SNP) | VAF 27/155 reads (17%) | catalogued as COSV51697753; called by muse, mutect2, varscan2
- SLC22A14 | c.1625T>A p.I542N | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV56199096; called by muse, mutect2, varscan2
- SRCAP | c.9398C>A p.T3133N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.017); catalogued as COSV52679474; called by muse, mutect2, varscan2
- SYT12 | c.1213T>A p.L405M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.795); catalogued as COSV67354778; called by muse, mutect2, varscan2
- ZFAND4 | c.565A>T p.M189L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100084413; called by muse, mutect2
- ZFAND4 | c.563G>C p.R188P | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.036); catalogued as rs769933468, COSV100084414, COSV58898176; called by muse, mutect2
- ZNF492 | c.1445G>A p.C482Y | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV71762330; called by muse, mutect2, varscan2
- ZSCAN2 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV100306752; called by muse, mutect2
- FBN3 | c.1399_1401del p.P467del | In Frame Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- IGKV3D-20 | c.145G>T p.V49F | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2
- IGLV3-9 | c.329A>C p.D110A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by mutect2, varscan2
- JPH1 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.165); called by muse, mutect2
- ADAMTS19 | c.1422T>C p.I474= | Silent (SNP) | VAF 7/137 reads (5%) | catalogued as COSV99176155; called by muse, mutect2
- ADGRL4 | c.1137C>T p.T379= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV66061771; called by muse, mutect2
- CTTNBP2 | c.1752G>A p.V584= | Silent (SNP) | VAF 121/179 reads (68%) | catalogued as COSV50459003; called by muse, mutect2, varscan2
- DSCAM | c.1143C>T p.G381= | Silent (SNP) | VAF 110/474 reads (23%) | catalogued as rs372861546; called by muse, mutect2, varscan2
- FASTKD3 | c.1053T>C p.F351= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs780635696, COSV52946315; called by muse, mutect2, varscan2
- H2BC6 | c.57G>T p.V19= | Silent (SNP) | VAF 37/205 reads (18%) | catalogued as COSV61591144, COSV61591646; called by muse, mutect2, varscan2
- HDAC7 | c.1290C>T p.G430= (on ENST00000427332; = p.G469= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99315278; called by muse, mutect2
- INHBE | c.1029G>A p.V343= | Silent (SNP) | VAF 12/249 reads (5%) | catalogued as rs1458111812, COSV99875145; called by muse, mutect2
- KIF27 | c.1014A>C p.A338= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV52830664; called by muse, mutect2, varscan2
- MKNK1 | c.60G>T p.R20= | Silent (SNP) | VAF 39/211 reads (18%) | catalogued as COSV57862668; called by muse, mutect2, varscan2
- MMP21 | c.783C>T p.D261= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs41306007; called by muse, mutect2, varscan2
- PDE11A | c.1221C>A p.V407= | Silent (SNP) | VAF 62/203 reads (31%) | catalogued as COSV53705927; called by muse, mutect2, varscan2
- PDZRN3 | c.2874C>A p.T958= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- PTPRN | c.1329C>T p.V443= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs151307858; called by muse, mutect2, varscan2
- RYR1 | c.9897C>T p.G3299= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs780548929, COSV62108244; called by muse, mutect2, varscan2
- SRCAP | c.5610C>T p.P1870= | Silent (SNP) | VAF 16/227 reads (7%) | catalogued as rs141985098; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- SYT17 | c.762C>G p.P254= | Silent (SNP) | VAF 16/550 reads (3%) | called by muse, mutect2
- TEK | c.1188A>G p.K396= | Silent (SNP) | VAF 14/233 reads (6%) | catalogued as COSV101193033; called by muse, mutect2
- TGFBR3 | c.1617T>C p.G539= | Silent (SNP) | VAF 32/708 reads (5%) | catalogued as COSV99282179; called by muse, mutect2
- TPBG | c.714C>T p.H238= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV63883011; called by muse, mutect2, varscan2
- GRIA4 | c.1269+1362G>C | Intron (SNP) | VAF 6/93 reads (6%) | catalogued as COSV99227811, COSV99229519; called by muse, mutect2
- RAPGEF5 | chr7:22194017 G>A | 5'Flank (SNP) | VAF 40/306 reads (13%) | catalogued as rs375862364; called by muse, mutect2, varscan2
